Somatic mutation profile of cancer-model specimen HCM-BROD-0134-C25-85A (3D Organoid, passage 6; aliquot HCM-BROD-0134-C25-85A-01D-A786-36), derived from the metastatic tumor of HCMI case HCM-BROD-0134-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 63.0 years (22,999 days).
Specimen HCM-BROD-0134-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c43bf1c-7047-4fac-92b1-fd8836aee5ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0134-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0134-C25-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d8e370d-c6c8-4fe0-9eda-f61e9e2a2756

The open-access MAF lists 60 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 10, Intron 5, RNA 3, Frame Shift Ins 2, Nonsense Mutation 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 165/310 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATG2A | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 423/625 reads (68%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.928); catalogued as rs1280384777, COSV65966155; called by muse, mutect2, varscan2
- CDC42BPG | c.1883C>G p.P628R | Missense Mutation (SNP) | VAF 78/276 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.199); catalogued as rs144502189, COSV61347777; called by muse, mutect2, varscan2
- CELA2A | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 89/310 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs184256573; called by muse, mutect2, varscan2
- CEMIP2 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs771902134, COSV65487651; called by muse, mutect2, varscan2
- CPT1C | c.97C>A p.L33I | Missense Mutation (SNP) | VAF 103/682 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV54920996; called by muse, mutect2, varscan2
- CTNNA3 | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 234/528 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101051816; called by muse, mutect2, varscan2
- CYP27C1 | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775859403; called by muse, mutect2, varscan2
- FDX2 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 75/217 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.013); catalogued as rs1414127378; called by muse, mutect2, varscan2
- FLACC1 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs760942539; called by muse, mutect2, varscan2
- FMN2 | c.3409G>A p.G1137R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.619); catalogued as rs761207412, COSV60435090; called by muse, varscan2
- HECTD4 | c.3487C>A p.R1163S | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV61179586; called by muse, mutect2, varscan2
- KCTD16 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 129/189 reads (68%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as COSV72578389; called by muse, mutect2, varscan2
- KL | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs747178287; called by muse, mutect2, varscan2
- KLHL10 | c.1418T>C p.I473T | Missense Mutation (SNP) | VAF 89/268 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs782436117; called by muse, mutect2, varscan2
- MFAP3L | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs200379070, COSV64372338; called by muse, mutect2, varscan2
- MGAM | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 73/119 reads (61%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as COSV101516455; called by mutect2, varscan2
- NOXA1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs756433242; called by muse, mutect2, varscan2
- OR5K2 | c.770dup p.L258Pfs*4 | Frame Shift Ins (INS) | VAF 29/149 reads (19%) | catalogued as rs747087385; called by mutect2, varscan2
- OTOA | c.1753G>A p.V585M (on ENST00000286149; = p.V571M on NM_144672.4) | Missense Mutation (SNP) | VAF 144/513 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as rs568684216; called by muse, mutect2, varscan2
- PCDH10 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV52088168, COSV52103034; called by muse, mutect2
- RNF180 | c.240G>A p.W80* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as rs1228435865; called by muse, mutect2, varscan2
- SLFN14 | c.880A>G p.T294A | Missense Mutation (SNP) | VAF 137/139 reads (99%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs1299408239; called by muse, mutect2, varscan2
- TAT | c.536T>C p.M179T | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.131); catalogued as rs1230078415; called by muse, mutect2, varscan2
- ZNF2 | c.785G>A p.R262Q (on ENST00000611147 / NM_001291605.2; = p.R249Q on NM_021088.4) | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs745543447; called by muse, mutect2, varscan2
- ZNF497 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 88/502 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1296249704; called by muse, mutect2, varscan2
- C5 | c.2924G>T p.R975M | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- CDK13 | c.353del p.R118Lfs*23 | Frame Shift Del (DEL) | VAF 11/20 reads (55%) | called by mutect2, pindel, varscan2
- COL4A2 | c.2558T>C p.L853S | Missense Mutation (SNP) | VAF 104/185 reads (56%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- DDX60 | c.2921T>C p.V974A | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- DST | c.18562G>A p.G6188R (on ENST00000361203 / NM_001374722.1; = p.G3885R on NM_015548.5) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSD1L | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- KHNYN | c.1046A>G p.N349S | Missense Mutation (SNP) | VAF 117/161 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- PDX1 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 77/143 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RAET1G | c.869C>A p.S290Y | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- RNF150 | c.957G>T p.K319N | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RXFP1 | c.1523T>C p.L508S | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SH3RF3 | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 161/542 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TP53 | c.245_248dup p.A84Gfs*66 | Frame Shift Ins (INS) | VAF 154/174 reads (89%) | called by mutect2, pindel, varscan2
- ZNF628 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 30/668 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2
- ZNF700 | c.1346A>G p.K449R | Missense Mutation (SNP) | VAF 114/247 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- AK8 | c.798G>A p.P266= | Silent (SNP) | VAF 92/131 reads (70%) | catalogued as rs142140228; called by muse, mutect2, varscan2
- ATPSCKMT | c.456G>A p.S152= | Silent (SNP) | VAF 67/186 reads (36%) | catalogued as rs767986624; called by muse, mutect2, varscan2
- DNAH11 | c.4890C>T p.F1630= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as rs569494115, COSV60945336; ClinVar: likely benign; called by muse, mutect2, varscan2
- DTX1 | c.705G>A p.P235= | Silent (SNP) | VAF 19/152 reads (13%) | catalogued as rs1423394006; called by muse, mutect2, varscan2
- MMP21 | c.114G>A p.P38= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV100916708; called by muse, mutect2
- OR8K1 | c.879G>A p.P293= | Silent (SNP) | VAF 49/76 reads (64%) | catalogued as rs545105332, COSV54403279; called by muse, mutect2, varscan2
- PITPNM1 | c.3054C>T p.R1018= | Silent (SNP) | VAF 65/244 reads (27%) | catalogued as rs1186558088; called by muse, mutect2, varscan2
- RGL1 | c.99G>A p.Q33= (on ENST00000360851 / NM_001297672.2; = p.Q68= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 48/178 reads (27%) | called by muse, mutect2, varscan2
- TBL3 | c.1098G>A p.T366= | Silent (SNP) | VAF 116/481 reads (24%) | catalogued as rs779366606; called by muse, mutect2, varscan2
- XIRP1 | c.5526C>T p.A1842= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as COSV100453918; called by muse, mutect2, varscan2
- AKR1C1 | c.570+732C>T | Intron (SNP) | VAF 126/203 reads (62%) | catalogued as rs557286374; called by muse, mutect2, varscan2
- DCHS2 | n.6450C>T | RNA (SNP) | VAF 35/75 reads (47%) | catalogued as COSV100602751; called by muse, mutect2, varscan2
- EXOC7 | c.1929+36G>A | Intron (SNP) | VAF 88/365 reads (24%) | called by muse, mutect2, varscan2
- LIMCH1 | c.936-9264C>A | Intron (SNP) | VAF 108/228 reads (47%) | catalogued as rs543172439; called by mutect2, varscan2
- MTTP | c.-73C>T | 5'UTR (SNP) | VAF 97/238 reads (41%) | called by muse, mutect2, varscan2
- NPIPB1P | n.552A>C | RNA (SNP) | VAF 263/455 reads (58%) | called by muse, mutect2, varscan2
- SHB | c.838+561G>A | Intron (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- SNORD114-13 | n.48C>G | RNA (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- SNRNP200 | c.4164+50G>T | Intron (SNP) | VAF 108/156 reads (69%) | called by muse, mutect2, varscan2
